Somatic mutation profile of tumor specimen MMRF_2487_1_BM_CD138pos (aliquot MMRF_2487_1_BM_CD138pos_T1_KHS5U_L11629) from MMRF case MMRF_2487, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,124 days).
Specimen MMRF_2487_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7936274-cf86-44ea-bd5b-4b762a65e0ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2487_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2487_1_PB_Whole_C3_KHS5U_L11630; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12ba638c-ef26-404a-865b-b8d4df538b6d

The open-access MAF lists 129 somatic variants for this specimen: 56 protein-altering or splice-affecting, 11 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 29, Intron 19, Silent 11, 5'UTR 5, 3'Flank 5, RNA 2, 5'Flank 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 132/260 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 89/492 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1C4 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs782606168, COSV54122384; called by muse, mutect2, varscan2
- CCDC6 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1256572017, COSV54058541; called by muse, mutect2, varscan2
- CREBBP | c.4282C>T p.R1428C | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387351570, COSV52121437; called by muse, mutect2, varscan2
- EGLN1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100791219; called by muse, mutect2
- FAT2 | c.3607G>C p.E1203Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV55816165; called by muse, mutect2, varscan2
- FIBCD1 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs751954546; called by muse, mutect2, varscan2
- FREM2 | c.4964T>C p.V1655A | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs745577885; called by muse, mutect2, varscan2
- GABRE | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.264); catalogued as rs887036619, COSV64819010; called by muse, mutect2, varscan2
- GPR141 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57732411; called by muse, mutect2, varscan2
- IGHV2-70 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs374665565; called by muse, varscan2
- IGLV3-1 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 90/98 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs534241034; called by muse, mutect2, varscan2
- IGLV5-37 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs772294417; called by muse, varscan2
- IGLV7-46 | c.320A>T p.Y107F | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs191717127; called by muse, mutect2, varscan2
- KRT19 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV64238206; called by muse, mutect2, varscan2
- NLRP12 | c.2086G>A p.V696I | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs568227595, COSV100145949; called by muse, mutect2, varscan2
- OR2B2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs930939827, COSV57579181; called by muse, mutect2, varscan2
- POLRMT | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748877796; called by muse, mutect2, varscan2
- RUSC1 | c.1194_1220del p.P401_R409del | In Frame Del (DEL) | VAF 44/67 reads (66%) | catalogued as rs1472927673; called by mutect2, pindel, varscan2
- STK10 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.025); catalogued as rs369344814; called by muse, mutect2, varscan2
- TBC1D16 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs760596832; called by muse, mutect2, varscan2
- TMSB4X | c.-17+1G>A | Splice Site (SNP) | VAF 65/71 reads (92%) | catalogued as COSV66081196, COSV66081636; called by muse, mutect2, varscan2
- TSHZ3 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 62/691 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs555294304, COSV99551036; called by muse, mutect2
- WFDC8 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1568992765; called by muse, mutect2, varscan2
- ZNF727 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1454227257, COSV101473402; called by muse, mutect2, varscan2
- ACSS2 | c.1766T>G p.V589G | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- AMPD1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD31 | c.3737A>C p.N1246T | Missense Mutation (SNP) | VAF 78/109 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD50 | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- CATSPERB | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- CFAP47 | c.599T>A p.M200K | Missense Mutation (SNP) | VAF 106/131 reads (81%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COLGALT2 | c.533T>A p.L178H | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CORO1A | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIO2 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK7 | c.5510G>A p.R1837Q (on ENST00000635253 / NM_001367561.1; = p.R1806Q on NM_033407.3) | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EEPD1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 111/182 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG2 | c.6786A>C p.E2262D | Missense Mutation (SNP) | VAF 175/345 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGLV5-37 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, varscan2
- IGLV5-45 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, varscan2
- KLC2 | c.1676T>C p.M559T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KLF2 | c.1031_1046del p.S344Cfs*3 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | called by mutect2, pindel, varscan2
- NAP1L3 | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, varscan2
- NEMP1 | c.1039T>C p.Y347H (on ENST00000300128 / NM_001130963.2; = p.Y274H on NM_015257.3) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NTN3 | c.406A>C p.K136Q | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGAP6 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP8 | c.1466A>C p.K489T | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROGDI | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- SEC24A | c.1516T>A p.Y506N | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3TC2 | c.3473T>G p.V1158G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SMPD2 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SMTN | c.2129C>A p.S710Y | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, varscan2
- TMBIM6 | c.273T>A p.F91L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM6 | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 131/191 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSIG10 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF618 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 107/344 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DLGAP3 | c.2460G>A p.A820= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as rs139693504; called by muse, mutect2, varscan2
- IGLV5-45 | c.198G>A p.Q66= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as rs187611736; called by muse, varscan2
- INSC | c.1728G>A p.E576= | Silent (SNP) | VAF 110/317 reads (35%) | called by muse, mutect2, varscan2
- L1TD1 | c.30A>C p.S10= | Silent (SNP) | VAF 63/163 reads (39%) | called by muse, mutect2, varscan2
- MUC22 | c.5208A>G p.G1736= | Silent (SNP) | VAF 78/196 reads (40%) | called by muse, mutect2
- OGT | c.1767C>T p.F589= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV101035587; called by muse, mutect2
- PCDH17 | c.663T>A p.P221= | Silent (SNP) | VAF 142/299 reads (47%) | catalogued as COSV100931460; called by muse, mutect2, varscan2
- PMP22 | c.432C>T p.P144= | Silent (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.1578C>G p.S526= | Silent (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- UNC13B | c.1872C>T p.Y624= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as rs144394180; called by muse, mutect2, varscan2
- ZNF728 | c.312A>G p.E104= | Silent (SNP) | VAF 57/180 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.*256A>G | 3'UTR (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- AK3 | c.-94C>T | 5'UTR (SNP) | VAF 19/53 reads (36%) | catalogued as rs1162935348; called by muse, mutect2, varscan2
- AKAP9 | c.4917+48A>C | Intron (SNP) | VAF 69/100 reads (69%) | called by muse, varscan2
- ARHGAP28 | c.2030+1719C>A | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, varscan2
- BHLHA9 | c.*152C>T | 3'UTR (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- BTBD11 | c.*330C>T | 3'UTR (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- C10orf88B | n.248T>G | RNA (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- C2orf49 | c.*1235G>T | 3'UTR (SNP) | VAF 45/81 reads (56%) | called by muse, mutect2, varscan2
- CCDC163 | c.*157C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- CCDC32 | chr15:40531603 A>C | 3'Flank (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- CCKAR | c.-80C>T | 5'UTR (SNP) | VAF 14/82 reads (17%) | catalogued as rs1292496699, COSV55162913; called by muse, mutect2, varscan2
- CD2AP | c.*1786T>C | 3'UTR (SNP) | VAF 24/64 reads (38%) | catalogued as rs558664143; called by muse, mutect2, varscan2
- CFLAR | c.1305-620T>G | Intron (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- CYLD | chr16:50806692 T>G | 3'Flank (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- DPP6 | c.244-140895G>A | Intron (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- DPYSL5 | c.*590C>T | 3'UTR (SNP) | VAF 48/90 reads (53%) | catalogued as rs999490638; called by muse, mutect2, varscan2
- ELOVL7 | c.*2796T>C | 3'UTR (SNP) | VAF 81/118 reads (69%) | called by muse, mutect2, varscan2
- EMSY | chr11:76552695 C>T | 3'Flank (SNP) | VAF 61/119 reads (51%) | catalogued as rs1022547803; called by muse, mutect2, varscan2
- GTF2H1 | c.838-30A>T | Intron (SNP) | VAF 50/90 reads (56%) | catalogued as COSV56378822; called by muse, mutect2
- HS6ST1 | c.*2535C>A | 3'UTR (SNP) | VAF 30/268 reads (11%) | called by muse, mutect2
- IFIT2 | c.*1099T>C | 3'UTR (SNP) | VAF 23/48 reads (48%) | catalogued as rs1188871335; called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863423 T>A | 5'Flank (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- ITGA1 | c.*825A>G | 3'UTR (SNP) | VAF 46/82 reads (56%) | called by muse, mutect2, varscan2
- KCNMB3 | c.68+49T>C | Intron (SNP) | VAF 98/218 reads (45%) | called by muse, mutect2, varscan2
- KIRREL3 | c.*738C>T | 3'UTR (SNP) | VAF 48/113 reads (42%) | called by muse, mutect2, varscan2
- LDHC | chr11:18451525 T>G | 3'Flank (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.573+2265A>G | Intron (SNP) | VAF 44/102 reads (43%) | catalogued as rs565164319, COSV63048484; called by muse, mutect2, varscan2
- LRRIQ3 | c.573+2013T>G | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as rs944226385; called by muse, mutect2, varscan2
- MALRD1 | c.5030-2443G>A | Intron (SNP) | VAF 133/259 reads (51%) | catalogued as rs1274821019, COSV65969531; called by muse, mutect2, varscan2
- MEF2C | c.*1744_*1745del | 3'UTR (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- MGLL | c.*1551A>G | 3'UTR (SNP) | VAF 46/131 reads (35%) | called by muse, mutect2, varscan2
- NCBP1 | c.-43T>C | 5'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- NFATC4 | chr14:24367186 T>C | 5'Flank (SNP) | VAF 91/192 reads (47%) | called by muse, mutect2, varscan2
- NOB1 | c.525+33G>T | Intron (SNP) | VAF 48/171 reads (28%) | called by muse, varscan2
- NPY2R | c.-4G>A | 5'UTR (SNP) | VAF 57/116 reads (49%) | catalogued as rs867284773; called by muse, mutect2, varscan2
- PAH | c.*777T>A | 3'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- PAX2 | c.44-101G>A | Intron (SNP) | VAF 55/122 reads (45%) | catalogued as rs778796089; called by muse, mutect2, varscan2
- PRKACB | c.47-14308T>G | Intron (SNP) | VAF 122/252 reads (48%) | called by muse, mutect2, varscan2
- PROS1 | c.*1124T>G | 3'UTR (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- PRRG1 | c.*528A>T | 3'UTR (SNP) | VAF 29/33 reads (88%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+963A>C | Intron (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- PTPA | c.*1407C>T | 3'UTR (SNP) | VAF 97/160 reads (61%) | called by muse, mutect2, varscan2
- PTPN3 | c.*2661G>A | 3'UTR (SNP) | VAF 5/101 reads (5%) | catalogued as rs868636047; called by muse, mutect2
- RGMA | c.15-881G>A | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- RNF4 | c.*1425G>A | 3'UTR (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- RSPO2 | c.*1047del | 3'UTR (DEL) | VAF 36/82 reads (44%) | called by mutect2, pindel, varscan2
- SATB2 | c.*1239T>G | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.-18C>T | 5'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- SLC7A8 | c.1114-68C>T | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as rs1029421815; called by muse, mutect2
- SLC8B1 | c.*1010T>C | 3'UTR (SNP) | VAF 4/61 reads (7%) | catalogued as rs1005169956; called by muse, mutect2
- SLIT2 | c.*702T>G | 3'UTR (SNP) | VAF 42/72 reads (58%) | called by muse, varscan2
- SMTN | c.1633-1590C>T | Intron (SNP) | VAF 35/103 reads (34%) | called by muse, varscan2
- SMTN | c.1633-1522C>T | Intron (SNP) | VAF 29/78 reads (37%) | catalogued as rs1381252223; called by muse, varscan2
- SMTN | c.2090-58C>G | Intron (SNP) | VAF 22/56 reads (39%) | called by muse, varscan2
- SRF | c.*833C>T | 3'UTR (SNP) | VAF 16/38 reads (42%) | catalogued as rs564905026; called by muse, mutect2, varscan2
- TMEM268 | c.*376T>G | 3'UTR (SNP) | VAF 55/159 reads (35%) | called by muse, mutect2, varscan2
- TPBG | c.*204T>G | 3'UTR (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- TRIML1 | c.*18G>A | 3'UTR (SNP) | VAF 21/49 reads (43%) | catalogued as rs373633936; called by muse, mutect2, varscan2
- TRIQK | chr8:92884133 A>C | 3'Flank (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- TRPC6 | c.*1002A>G | 3'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3493C>T | Intron (SNP) | VAF 59/159 reads (37%) | catalogued as rs1352827991; called by muse, mutect2, varscan2
- ZNF812P | n.1204C>T | RNA (SNP) | VAF 70/308 reads (23%) | called by muse, mutect2, varscan2
